Somatic mutation profile of tumor specimen TCGA-56-8305-01A (aliquot TCGA-56-8305-01A-11D-2293-08) from TCGA case TCGA-56-8305, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.4 years (26,428 days).
Specimen TCGA-56-8305-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c400a71-c89e-4942-a4d0-887f30683824.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-8305-11A (Solid Tissue Normal), aliquot TCGA-56-8305-11A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ec868b8-87a1-465f-add4-6c3131b50266

The open-access MAF lists 409 somatic variants for this specimen: 301 protein-altering or splice-affecting, 99 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 257, Silent 99, Nonsense Mutation 21, Splice Site 9, Frame Shift Del 8, Splice Region 4, Intron 4, 5'Flank 2, Frame Shift Ins 1, Nonstop Mutation 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.3539-1G>C p.X1180_splice | Splice Site (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100750656, COSV100750773; called by muse, mutect2, varscan2
- ACSM4 | c.1741T>C p.*581Qext*17 | Nonstop Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as rs1030511087, COSV68068433; called by muse, mutect2, varscan2
- ACTN4 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs759789993, COSV53146321; called by muse, mutect2, varscan2
- ACVR1B | c.517C>G p.L173V | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV99231509; called by muse, mutect2, varscan2
- ADAM2 | c.835G>C p.G279R | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99697345, COSV99697588; called by muse, mutect2, varscan2
- ADAMTS16 | c.2287C>A p.H763N | Missense Mutation (SNP) | VAF 63/396 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as COSV99941278, COSV99941965; called by muse, mutect2, varscan2
- ADAMTS18 | c.2240C>G p.T747S | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV99272721; called by muse, mutect2, varscan2
- ADH1C | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.275); catalogued as COSV101565183; called by muse, mutect2, varscan2
- AGMO | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100694177; called by muse, mutect2, varscan2
- AKAP6 | c.3589-1G>T p.X1197_splice | Splice Site (SNP) | VAF 23/93 reads (25%) | catalogued as COSV99800972; called by muse, mutect2, varscan2
- ANKRD49 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as COSV100119695; called by muse, mutect2, varscan2
- ANO4 | c.906T>A p.Y302* (on ENST00000392977 / NM_001286615.2; = p.Y267* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 46/201 reads (23%) | catalogued as COSV100152924, COSV54613147; called by muse, mutect2, varscan2
- APC | c.6749G>T p.G2250V | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as rs1247815306, COSV99967907; called by muse, mutect2, varscan2
- ARHGAP29 | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 24/169 reads (14%) | catalogued as COSV53110295, COSV99558207; called by muse, mutect2, varscan2
- ARID2 | c.1097G>T p.R366M | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100536234; called by muse, mutect2, varscan2
- ARID5B | c.89A>T p.E30V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV99689717; called by muse, mutect2, varscan2
- ART4 | c.860G>A p.S287N | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV99966908; called by muse, mutect2, varscan2
- ASTN1 | c.1776G>T p.E592D | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.969); catalogued as COSV56077720; called by muse, mutect2, varscan2
- ASXL3 | c.1121C>G p.T374S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99325001; called by muse, mutect2, varscan2
- ATP10B | c.517G>T p.G173* | Nonsense Mutation (SNP) | VAF 50/137 reads (36%) | catalogued as COSV58777610; called by muse, varscan2
- ATRNL1 | c.2020G>T p.A674S | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.137); catalogued as COSV100745625; called by muse, mutect2, varscan2
- BARHL2 | c.609C>A p.S203R | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100966056, COSV64981835; called by muse, mutect2, varscan2
- BBX | c.1980G>T p.W660C | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV100361597; called by muse, mutect2, varscan2
- BEND6 | c.277C>A p.Q93K | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV100876852; called by muse, mutect2, varscan2
- BFSP2 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100183768; called by mutect2, varscan2
- BPI | c.1111G>T p.D371Y (on ENST00000262865; = p.D367Y on NM_001725.3) | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99480654; called by muse, mutect2, varscan2
- C10orf88 | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.255); catalogued as rs1205230635, COSV100925019; called by muse, mutect2, varscan2
- C12orf40 | c.333C>A p.T111= | Splice Region (SNP) | VAF 47/195 reads (24%) | catalogued as COSV100210110; called by muse, varscan2
- C8orf74 | c.200A>T p.Q67L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.215); catalogued as COSV100261972; called by muse, mutect2, varscan2
- CABIN1 | c.3433G>T p.E1145* | Nonsense Mutation (SNP) | VAF 44/160 reads (28%) | catalogued as COSV99573248; called by muse, mutect2, varscan2
- CCDC14 | c.2264G>T p.R755I (on ENST00000488653; = p.R707I on NM_022757.5) | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100113230; called by muse, mutect2, varscan2
- CCDC39 | c.1885C>G p.R629G | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99868953; called by muse, mutect2, varscan2
- CCZ1B | c.518A>T p.H173L | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100367857; called by muse, mutect2, varscan2
- CD1A | c.893G>C p.S298T | Missense Mutation (SNP) | VAF 65/374 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV99192386; called by muse, mutect2, varscan2
- CDH10 | c.1921G>T p.E641* | Nonsense Mutation (SNP) | VAF 56/115 reads (49%) | catalogued as COSV100051549, COSV52586321; called by muse, mutect2, varscan2
- CDH10 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as rs1203279001, COSV100050385, COSV100051550; called by muse, mutect2, varscan2
- CDH10 | c.602G>C p.S201T | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100051555; called by muse, varscan2
- CDKL3 | c.1237A>G p.T413A | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99527873; called by muse, mutect2, varscan2
- CDX2 | c.574G>T p.V192L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV101122682; called by muse, mutect2, varscan2
- CEP162 | c.4099G>T p.E1367* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as COSV100002826; called by muse, mutect2, varscan2
- CFLAR | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100009405; called by muse, mutect2, varscan2
- CGB1 | c.451C>A p.R151S | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV56819700; called by muse, mutect2, varscan2
- CHIT1 | c.800A>T p.Y267F | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV99705312; called by muse, mutect2, varscan2
- CHRNB3 | c.869C>A p.S290Y | Missense Mutation (SNP) | VAF 96/237 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51495176, COSV99251196; called by muse, mutect2, varscan2
- CNTNAP4 | c.3236G>T p.R1079M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271536; called by muse, mutect2, varscan2
- COG6 | c.1477G>T p.G493C | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs1207071017, COSV100742913; called by muse, varscan2
- COG6 | c.1478G>T p.G493V | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as rs1275224517, COSV100742918; called by muse, varscan2
- COL15A1 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV100897694; called by muse, mutect2, varscan2
- COL1A2 | c.3277G>A p.G1093S | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51966275, COSV99799787; called by muse, mutect2, varscan2
- COL22A1 | c.4424A>T p.Q1475L | Missense Mutation (SNP) | VAF 127/434 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.953); catalogued as COSV100278586; called by muse, mutect2, varscan2
- CSMD3 | c.8036C>A p.T2679K (on ENST00000297405 / NM_001363185.1; = p.T2575K on NM_052900.3) | Missense Mutation (SNP) | VAF 101/325 reads (31%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.755); catalogued as COSV52306358; called by muse, mutect2, varscan2
- CUL4A | c.971A>G p.Q324R (on ENST00000375440 / NM_001008895.4; = p.Q224R on NM_003589.3) | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV100417265; called by muse, mutect2, varscan2
- CUX1 | c.2482G>T p.V828L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs373335029, COSV52891957; called by muse, mutect2, varscan2
- CXorf38 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100010393; called by muse, mutect2, varscan2
- CYLC1 | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100254657; called by muse, varscan2
- CYP27A1 | c.1524G>T p.L508F | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV99298509; called by muse, mutect2, varscan2
- DAGLA | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 101/303 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV104377700, COSV99944396; called by muse, mutect2, varscan2
- DBF4B | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100154521; called by muse, mutect2, varscan2
- DCAF12L2 | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.356); catalogued as COSV63584142; called by muse, mutect2, varscan2
- DCT | c.1218G>C p.W406C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100986218; called by muse, mutect2, varscan2
- DEFB121 | c.143C>A p.A48D | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV100889987; called by muse, mutect2, varscan2
- DGKI | c.2115C>A p.S705R | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.677); catalogued as COSV99934690; called by muse, mutect2, varscan2
- DHX33 | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV99834362; called by muse, mutect2, varscan2
- DMKN | c.1105G>T p.G369C | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs758644807, COSV60086076; called by muse, mutect2, varscan2
- DNAJC25 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV100543370; called by muse, mutect2, varscan2
- DTNA | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as COSV99312887, COSV99316551; called by muse, mutect2, varscan2
- ECT2 | c.868G>T p.E290* (on ENST00000392692 / NM_001349098.2; = p.E259* on NM_018098.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | catalogued as COSV99221384; called by muse, mutect2, varscan2
- EDNRB | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | catalogued as COSV100526671; called by muse, mutect2, varscan2
- EGFLAM | c.1092G>T p.W364C | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.428); catalogued as rs1330820237, COSV100380304; called by muse, mutect2, varscan2
- EIF3K | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as COSV99943042; called by muse, mutect2, varscan2
- ERBB4 | c.3391G>T p.D1131Y | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100725829, COSV61467184; called by muse, varscan2
- ERF | c.1192G>T p.G398C | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV99724668; called by muse, mutect2, varscan2
- ERO1A | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as COSV101193631; called by mutect2, varscan2
- EVC2 | c.2282A>T p.Q761L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100186005; called by muse, mutect2, varscan2
- EYA4 | c.562T>C p.Y188H | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100765872; called by muse, mutect2, varscan2
- EYS | c.1370A>G p.H457R | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV100676475; called by muse, mutect2, varscan2
- F11R | c.774G>T p.W258C | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99231051; called by muse, mutect2, varscan2
- FANCL | c.929G>C p.C310S | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99287596; called by muse, mutect2, varscan2
- FAP | c.1002G>T p.K334N | Missense Mutation (SNP) | VAF 50/388 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.424); catalogued as rs746205629, COSV99502182; called by muse, mutect2, varscan2
- FCGBP | c.8101A>G p.I2701V | Missense Mutation (SNP) | VAF 48/680 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.087); catalogued as COSV99662381; called by muse, mutect2
- FILIP1 | c.951G>A p.M317I | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV99384409, COSV99384908; called by muse, mutect2, varscan2
- FOXRED1 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV99702749; called by muse, mutect2, varscan2
- GABRA6 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV99194522; called by muse, mutect2, varscan2
- GALNT14 | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100204729; called by muse, mutect2, varscan2
- GBP5 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100600074; called by muse, mutect2, varscan2
- GLB1L3 | c.1453G>A p.G485R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV101345137; called by muse, mutect2, varscan2
- GLCE | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs552257481, COSV55944119; called by muse, mutect2
- GLYATL2 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs148535188, COSV99780382; called by mutect2, varscan2
- GOLGB1 | c.7747A>T p.N2583Y | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.175); catalogued as COSV100510887; called by muse, mutect2, varscan2
- GON4L | c.3628G>T p.G1210C | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV99674337; called by muse, mutect2, varscan2
- GPR141 | c.187A>G p.S63G | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV100550329; called by muse, mutect2, varscan2
- GRAMD1A | c.1475+1G>C p.X492_splice | Splice Site (SNP) | VAF 47/161 reads (29%) | catalogued as COSV100526180; called by muse, mutect2, varscan2
- GRIN2A | c.3395C>A p.P1132Q | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.009); catalogued as COSV100409852, COSV58020198; called by muse, mutect2, varscan2
- GRIN2B | c.1790G>A p.G597E | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101663039; called by muse, mutect2, varscan2
- GRM3 | c.2074T>A p.C692S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.928); catalogued as COSV100862557; called by muse, mutect2, varscan2
- GRM7 | c.1285C>T p.L429F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100736634; called by muse, mutect2, varscan2
- GSDMA | c.1325C>A p.T442N | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52857456; called by muse, mutect2, varscan2
- GTF2F1 | c.180G>T p.E60D | Missense Mutation (SNP) | VAF 100/318 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.231); catalogued as COSV101081249, COSV66725897; called by muse, mutect2, varscan2
- H2AC8 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); catalogued as rs1477519801, COSV99773237; called by muse, mutect2, varscan2
- HERC2 | c.3041A>C p.Q1014P | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99873944; called by muse, mutect2, varscan2
- HEXIM1 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 18/92 reads (20%) | catalogued as COSV100203492; called by muse, mutect2, varscan2
- HIPK3 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760366152, COSV100305800; called by muse, mutect2, varscan2
- HLCS | c.2042G>T p.G681V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754503384, COSV99293259; called by muse, mutect2, varscan2
- HOATZ | c.215G>C p.S72T | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.08); catalogued as COSV100239475; called by muse, mutect2, varscan2
- HTR5A | c.84C>A p.D28E | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV55287838, COSV99839715; called by muse, mutect2
- HTT | c.9055-2A>T p.X3019_splice | Splice Site (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100750783; called by muse, mutect2, varscan2
- IFFO1 | c.1082T>C p.M361T (on ENST00000396840 / NM_001330324.2; = p.M364T on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100351129; called by muse, mutect2, varscan2
- IL12RB2 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99255089; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1405C>G p.Q469E | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV56275076; called by muse, mutect2, varscan2
- ITGA10 | c.384G>T p.W128C | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100994914; called by muse, mutect2, varscan2
- ITGA10 | c.383G>T p.W128L | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100994913; called by muse, mutect2, varscan2
- ITGAX | c.3312C>A p.N1104K | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV99191724; called by muse, mutect2, varscan2
- ITPRID2 | c.2174A>T p.Y725F | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.415); catalogued as COSV100238287; called by muse, mutect2, varscan2
- ITSN1 | c.89A>G p.H30R | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.152); catalogued as rs1369976412, COSV101180530; called by muse, mutect2, varscan2
- JUP | c.2035G>T p.A679S | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as COSV100159580; called by muse, mutect2
- KARS1 | c.1326G>T p.R442S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100094096; called by muse, mutect2, varscan2
- KCNH4 | c.2077G>C p.D693H | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52916960, COSV99237215; called by muse, mutect2, varscan2
- KCNK13 | c.1085T>A p.I362N | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV99965710; called by muse, mutect2, varscan2
- KCNQ3 | c.2104G>T p.V702L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV101196145; called by muse, mutect2, varscan2
- KERA | c.508C>A p.L170I | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV57132024; called by muse, mutect2, varscan2
- KIAA1549L | c.3027C>A p.S1009R (on ENST00000321505; = p.S1306R on NM_012194.3) | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV99683540; called by muse, mutect2, varscan2
- KLHL25 | c.1501A>G p.T501A | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV100563589; called by muse, varscan2
- KLHL30 | c.220G>T p.V74L | Missense Mutation (SNP) | VAF 152/269 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs368732409, COSV100014320; called by muse, mutect2, varscan2
- KLHL4 | c.1713-1del p.X571_splice | Splice Site (DEL) | VAF 10/22 reads (45%) | catalogued as COSV64147246; called by mutect2, pindel, varscan2
- KMT5A | c.451G>C p.A151P | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100389498; called by muse, mutect2, varscan2
- KPNA1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1354135656, COSV60269761; called by muse, mutect2, varscan2
- KRTAP9-2 | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.482); catalogued as COSV100893187; called by muse, mutect2, varscan2
- KYNU | c.1041G>A p.E347= | Splice Region (SNP) | VAF 55/407 reads (14%) | catalogued as rs1483044652, COSV99933296; called by muse, mutect2, varscan2
- LHCGR | c.578C>A p.A193E | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99683732; called by muse, mutect2, varscan2
- LONRF2 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV101110938; called by muse, mutect2, varscan2
- LPO | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1342845086, COSV99228827; called by muse, mutect2, varscan2
- LRRC8A | c.2039A>T p.Q680L | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV99396623; called by muse, mutect2, varscan2
- MAGI3 | c.3835T>C p.C1279R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs755752623, COSV100289066; called by muse, mutect2, varscan2
- MATN4 | c.1357G>T p.V453F (on ENST00000372754; = p.V412F on NM_003833.4) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | PolyPhen probably damaging (0.99); catalogued as COSV100637028; called by muse, mutect2, varscan2
- MDGA2 | c.1393T>A p.S465T (on ENST00000399232 / NM_001113498.2; = p.S167T on NM_182830.4) | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.272); catalogued as COSV100637251; called by muse, mutect2, varscan2
- MED13L | c.1910G>C p.R637P | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV99928885; called by muse, mutect2, varscan2
- MELTF | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs372423742; called by muse, mutect2
- MEX3B | c.280G>C p.A94P | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100314040; called by muse, mutect2, varscan2
- MKRN3 | c.378G>T p.M126I | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV100091153; called by muse, mutect2, varscan2
- MS4A10 | c.753C>A p.D251E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.034); catalogued as COSV100382293; called by muse, mutect2, varscan2
- MSL2 | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.898); catalogued as COSV99387219; called by muse, mutect2, varscan2
- MSL2 | c.1336G>T p.G446* | Nonsense Mutation (SNP) | VAF 79/178 reads (44%) | catalogued as COSV99387220; called by muse, mutect2, varscan2
- MTRR | c.290G>T p.R97L (on ENST00000264668; = p.R70L on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/347 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs777202031, COSV52941860, COSV99241730; called by muse, mutect2, varscan2
- MTUS2 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as COSV101462229; called by muse, varscan2
- MUC16 | c.8777C>G p.S2926C | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as COSV101199992, COSV101200187; called by muse, mutect2, varscan2
- MUC4 | c.15721C>T p.R5241W (on ENST00000463781 / NM_018406.7; = p.R1005W on NM_004532.6) | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs376185784; called by muse, mutect2, varscan2
- MXRA5 | c.2974A>G p.K992E | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99477050; called by muse, mutect2, varscan2
- MYH15 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99843320; called by muse, mutect2, varscan2
- MYH15 | c.1426G>T p.G476C | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99843321; called by muse, mutect2, varscan2
- MYH2 | c.1898-2A>G p.X633_splice | Splice Site (SNP) | VAF 13/71 reads (18%) | catalogued as COSV99820178; called by muse, mutect2, varscan2
- MYO18B | c.5611A>G p.M1871V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs750262131, COSV100123725; called by muse, varscan2
- MYO7A | c.2747A>C p.K916T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.282); catalogued as COSV101289136; called by muse, mutect2
- NALCN | c.4835C>A p.P1612H | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as rs376113480, COSV51945661, COSV99215309; called by muse, mutect2, varscan2
- NAV3 | c.1826C>T p.T609I | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99891205; called by muse, mutect2, varscan2
- NF1 | c.5665G>T p.E1889* (on ENST00000358273 / NM_001042492.3; = p.E1868* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 42/98 reads (43%) | catalogued as CM143443, COSV62193500, COSV62204278, COSV62222668; called by muse, mutect2, varscan2
- NLGN1 | c.809T>A p.L270Q | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100849386; called by muse, mutect2, varscan2
- NLRP4 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV100016338; called by muse, mutect2
- NOVA1 | c.388A>T p.T130S | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.118); catalogued as COSV99947688; called by muse, mutect2, varscan2
- NPTX1 | c.990G>C p.Q330H | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100151020, COSV60774258; called by muse, varscan2
- OR10G4 | c.49del p.H17Mfs*30 | Frame Shift Del (DEL) | VAF 59/120 reads (49%) | catalogued as rs1565590933; called by mutect2, varscan2
- OR10J1 | c.116T>A p.L39* | Nonsense Mutation (SNP) | VAF 119/295 reads (40%) | catalogued as COSV101419891, COSV71129040; called by muse, mutect2, varscan2
- OR2L13 | c.905G>T p.R302I | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100813755; called by muse, mutect2, varscan2
- OR4A47 | c.309C>A p.H103Q | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101487066; called by muse, mutect2, varscan2
- OR4C12 | c.482C>G p.T161R | Missense Mutation (SNP) | VAF 84/345 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV100078506, COSV58860096; called by muse, mutect2, varscan2
- OR4C6 | c.728C>A p.T243K | Missense Mutation (SNP) | VAF 76/253 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV100051639, COSV58603342, COSV58603558; called by muse, mutect2, varscan2
- OR5M8 | c.692A>T p.E231V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV59117130; called by muse, mutect2, varscan2
- OR5W2 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100747631; called by muse, mutect2, varscan2
- OR6K2 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs755928722, COSV100656789; called by muse, mutect2, varscan2
- OR8D1 | c.798C>A p.N266K | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV100766647; called by muse, mutect2, varscan2
- OR8I2 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV56169278; called by muse, mutect2, varscan2
- OR8J3 | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100040846; called by muse, mutect2, varscan2
- P2RY1 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.89); catalogued as COSV100521699, COSV59310295; called by muse, mutect2, varscan2
- PABPC1L | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV99407824; called by muse, mutect2, varscan2
- PCDH15 | c.781T>A p.L261M | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV100221362; called by muse, mutect2, varscan2
- PCDHA1 | c.1233C>A p.S411R | Missense Mutation (SNP) | VAF 102/217 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.254); catalogued as COSV65377791; called by muse, mutect2, varscan2
- PCDHAC2 | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV53859393, COSV99148275; called by muse, mutect2, varscan2
- PDHX | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99927551, COSV99927646; called by muse, mutect2, varscan2
- PFKP | c.1227C>T p.T409= | Splice Region (SNP) | VAF 11/28 reads (39%) | catalogued as rs758494564, COSV101127251; called by muse, mutect2, varscan2
- PIK3C2G | c.2293G>T p.A765S (on ENST00000676171; = p.A724S on NM_004570.5) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs758616836, COSV99851633; called by muse, mutect2, varscan2
- PIK3R4 | c.818dup p.E275* | Frame Shift Ins (INS) | VAF 70/271 reads (26%) | catalogued as rs974249257; called by mutect2, pindel, varscan2
- PIP4P1 | c.600-2A>T p.X200_splice | Splice Site (SNP) | VAF 29/149 reads (19%) | catalogued as COSV99164483; called by muse, mutect2, varscan2
- PKD1L2 | c.78C>G p.S26R | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.157); catalogued as COSV100449904; called by muse, mutect2
- PKN2 | c.2168T>A p.L723H | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1165253894, COSV100981351, COSV100981431; called by muse, mutect2, varscan2
- PLEC | c.10711A>T p.T3571S (on ENST00000322810 / NM_201380.4; = p.T3461S on NM_000445.5) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as rs782257743, COSV100514357; called by muse, mutect2, varscan2
- PLPPR5 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.771); catalogued as COSV54168539, COSV99587321; called by muse, mutect2, varscan2
- POTEE | c.2761C>A p.L921M | Missense Mutation (SNP) | VAF 82/530 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.164); catalogued as COSV100387971; called by muse, varscan2
- POTEF | c.286A>G p.N96D | Missense Mutation (SNP) | VAF 153/377 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100664938; called by muse, mutect2, varscan2
- PPP1R32 | c.705G>C p.Q235H | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.195); catalogued as rs747776059, COSV100087827; called by muse, mutect2, varscan2
- PRKCG | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54723553; called by muse, mutect2, varscan2
- PRPF19 | c.1138A>T p.K380* | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | catalogued as COSV99920606; called by muse, mutect2, varscan2
- PRX | c.4193C>T p.A1398V | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as CM1410217, COSV52519569, COSV52519595; called by muse, mutect2
- PSIP1 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 55/136 reads (40%) | catalogued as COSV101050948; called by muse, mutect2, varscan2
- PTCH1 | c.4012C>T p.R1338C | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs374346190; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTGER2 | c.858G>T p.M286I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as COSV55418712, COSV55419520, COSV99817478; called by muse, varscan2
- PTPRB | c.434A>T p.Q145L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as COSV99717469; called by muse, mutect2, varscan2
- PTPRB | c.262G>T p.G88* | Nonsense Mutation (SNP) | VAF 44/177 reads (25%) | catalogued as COSV99717472; called by muse, mutect2, varscan2
- PYHIN1 | c.606C>A p.H202Q | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63723568, COSV63723785, COSV99058728; called by muse, mutect2, varscan2
- PZP | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767707066, COSV99737926; called by muse, mutect2, varscan2
- RBM11 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 90/385 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as COSV101271211; called by muse, varscan2
- REG1A | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV99286804; called by muse, mutect2, varscan2
- RGL2 | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.31); catalogued as COSV101442501; called by muse, mutect2, varscan2
- RHAG | c.863A>G p.D288G | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV100006617; called by muse, mutect2, varscan2
- RMI2 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100434924; called by muse, mutect2, varscan2
- RSPH6A | c.1475C>G p.T492R | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55570669, COSV55571101, COSV99679797; called by muse, mutect2, varscan2
- RUSC2 | c.741C>A p.D247E | Missense Mutation (SNP) | VAF 93/161 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100770722; called by muse, mutect2, varscan2
- RYR2 | c.4160G>T p.R1387I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as COSV63712575; called by muse, mutect2, varscan2
- RYR2 | c.8676C>G p.I2892M | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV100770313; called by muse, mutect2, varscan2
- RYR2 | c.12935T>A p.L4312Q | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.212); catalogued as COSV100770315; called by muse, mutect2, varscan2
- RYR3 | c.8237G>T p.W2746L (on ENST00000389232; = p.W2747L on NM_001036.6) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212799, COSV66810505; called by muse, mutect2, varscan2
- RYR3 | c.8238G>T p.W2746C (on ENST00000389232; = p.W2747C on NM_001036.6) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212800; called by muse, mutect2, varscan2
- SACS | c.4133C>T p.P1378L | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.045); catalogued as rs1311875583, COSV101207454; called by muse, mutect2
- SDR16C5 | c.856G>T p.G286* | Nonsense Mutation (SNP) | VAF 94/175 reads (54%) | catalogued as COSV58125473, COSV58127409; called by muse, mutect2, varscan2
- SEPTIN7 | c.370A>T p.S124C | Missense Mutation (SNP) | VAF 90/258 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.315); catalogued as COSV100621806; called by muse, mutect2, varscan2
- SEPTIN9 | c.1211C>T p.P404L (on ENST00000427177 / NM_001113491.2; = p.P386L on NM_006640.4) | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs777636409, COSV100218006; called by muse, mutect2
- SERPINB5 | c.947C>G p.S316* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV101237656; called by muse, mutect2, varscan2
- SERPINB7 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs908534450, COSV60532905; called by muse, mutect2, varscan2
- SERPINE1 | c.1121A>T p.E374V | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99776704; called by muse, mutect2, varscan2
- SFT2D1 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV100674933; called by muse, mutect2
- SH3TC1 | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs552621094, COSV55284475; called by muse, mutect2, varscan2
- SHOX | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV100479078; called by muse, mutect2, varscan2
- SIGLEC1 | c.2047G>T p.E683* | Nonsense Mutation (SNP) | VAF 37/142 reads (26%) | catalogued as COSV99165603; called by muse, mutect2, varscan2
- SIPA1L3 | c.4966G>T p.A1656S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99728856; called by muse, mutect2, varscan2
- SLC13A1 | c.1076T>C p.L359P | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99520941; called by muse, mutect2, varscan2
- SLC17A6 | c.146C>A p.P49H | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99581498; called by muse, mutect2, varscan2
- SLC22A16 | c.353G>C p.G118A | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57930306, COSV57933224; called by muse, mutect2, varscan2
- SLC22A9 | c.360G>T p.W120C | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208179251, COSV99655028; called by muse, mutect2, varscan2
- SLC26A9 | c.823C>A p.R275S | Missense Mutation (SNP) | VAF 70/351 reads (20%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.779); catalogued as COSV100536177, COSV100536387; called by muse, mutect2, varscan2
- SLC29A4 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.668); catalogued as rs746652680, COSV99786800; called by muse, mutect2, varscan2
- SLC39A1 | c.736T>C p.F246L | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV100135427; called by muse, mutect2
- SLC5A4 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV99831926; called by muse, mutect2, varscan2
- SLC5A5 | c.1052C>A p.T351N | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs374713485; called by muse, mutect2, varscan2
- SLFN13 | c.2032G>T p.G678W | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99540012; called by muse, mutect2, varscan2
- SLIT2 | c.2433C>A p.N811K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99883959; called by muse, mutect2, varscan2
- SPATA17 | c.353A>T p.K118I | Missense Mutation (SNP) | VAF 57/296 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100861132; called by muse, mutect2, varscan2
- SPIDR | c.1060G>A p.G354S | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.278); catalogued as COSV99855136; called by muse, varscan2
- SPSB4 | c.588C>A p.Y196* | Nonsense Mutation (SNP) | VAF 13/90 reads (14%) | catalogued as COSV100141357, COSV60146138; called by muse, mutect2, varscan2
- STPG1 | c.506G>C p.R169P (on ENST00000337248 / NM_001199013.2; = p.R122P on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/494 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV99134031; called by muse, mutect2, varscan2
- STXBP5 | c.2419A>G p.T807A (on ENST00000321680 / NM_001127715.2; = p.T771A on NM_139244.4) | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99470292; called by muse, varscan2
- SUCNR1 | c.745C>T p.H249Y | Missense Mutation (SNP) | VAF 45/466 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62911950; called by muse, mutect2, varscan2
- SUOX | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99907083; called by muse, mutect2, varscan2
- SYNE1 | c.19260G>T p.E6420D (on ENST00000367255 / NM_182961.4; = p.E6349D on NM_033071.3) | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV99564968; called by muse, mutect2, varscan2
- SYNE3 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV62080427; called by muse, mutect2, varscan2
- SYNJ1 | c.1423A>T p.I475F | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs763870801, COSV100449320; called by muse, mutect2, varscan2
- TAAR6 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99256716; called by muse, mutect2, varscan2
- TDRD3 | c.451G>C p.G151R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV99540372; called by muse, mutect2, varscan2
- TDRD5 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99676297; called by muse, mutect2, varscan2
- TEX37 | c.398del p.P133Rfs*31 | Frame Shift Del (DEL) | VAF 34/146 reads (23%) | catalogued as COSV100304565; called by mutect2, pindel, varscan2
- TFRC | c.2165A>G p.N722S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as COSV100786487; called by muse, mutect2, varscan2
- TLL1 | c.1679G>A p.G560E | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV99285961; called by muse, mutect2, varscan2
- TMEM225 | c.593C>A p.A198E | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as COSV66693777; called by muse, mutect2, varscan2
- TNFRSF8 | c.1348G>T p.G450C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.527); catalogued as COSV99821465; called by muse, mutect2, varscan2
- TOP2A | c.3158G>A p.R1053H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776759121, COSV70734338; called by muse, mutect2, varscan2
- TPSD1 | c.186G>T p.W62C | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99273883; called by muse, mutect2, varscan2
- TRABD2A | c.476A>G p.N159S | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100119927; called by muse, mutect2, varscan2
- TREML4 | c.171G>C p.Q57H | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100422918; called by muse, mutect2, varscan2
- TRPV2 | c.1610G>T p.R537L | Missense Mutation (SNP) | VAF 74/129 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100641217, COSV58428584; called by muse, mutect2, varscan2
- TTC21B | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs995718199, COSV54629796; called by muse, mutect2, varscan2
- TTN | c.24399A>T p.S8133= (on ENST00000591111; = p.S7206= on NM_133378.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100613913; called by muse, mutect2, varscan2
- USP16 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100537947; called by muse, mutect2, varscan2
- USP42 | c.463A>G p.M155V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); catalogued as COSV100084457; called by muse, mutect2, varscan2
- USP49 | c.1539C>G p.I513M | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV99790261; called by muse, mutect2, varscan2
- UTP20 | c.1781+2T>A p.X594_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99881659; called by muse, mutect2, varscan2
- VAT1 | c.1153C>A p.L385M | Missense Mutation (SNP) | VAF 134/676 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99887840; called by muse, mutect2, varscan2
- VKORC1L1 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV100663218; called by muse, mutect2
- VSTM2A | c.549C>A p.S183R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.424); catalogued as COSV100173110; called by muse, mutect2, varscan2
- WAPL | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 74/155 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100076845; called by muse, mutect2, varscan2
- WASHC5 | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100572838; called by muse, mutect2, varscan2
- XPNPEP3 | c.120G>T p.R40S | Missense Mutation (SNP) | VAF 95/351 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs765234342, COSV100846708; called by muse, mutect2, varscan2
- ZAR1 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747776385, COSV99906901; called by muse, mutect2, varscan2
- ZCCHC13 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100272521; called by muse, mutect2, varscan2
- ZEB2 | c.1274C>A p.P425H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100356066; called by muse, mutect2, varscan2
- ZMYM2 | c.3428A>G p.Y1143C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs368114931; called by muse, varscan2
- ZNF180 | c.1021A>T p.T341S | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.097); catalogued as COSV99659881; called by muse, mutect2, varscan2
- ZNF222 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV99496370; called by muse, mutect2
- ZNF285 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as COSV100450010; called by muse, mutect2
- ZNF311 | c.1177G>C p.G393R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV101014142, COSV65853519; called by muse, mutect2, varscan2
- ZNF311 | c.988C>G p.P330A | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as rs776492003, COSV101014143; called by muse, mutect2, varscan2
- ZNF329 | c.1521G>T p.R507S | Missense Mutation (SNP) | VAF 65/256 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV100798740; called by muse, mutect2, varscan2
- ZNF37A | c.1322G>T p.C441F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100697371; called by muse, mutect2, varscan2
- ZNF460 | c.1345G>T p.V449L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV100828082; called by muse, mutect2, varscan2
- ZNF479 | c.680A>G p.N227S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV100482759; called by muse, mutect2, varscan2
- ZNF526 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1401944628, COSV99725300; called by muse, mutect2, varscan2
- ZNF566 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 157/459 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as COSV101091409; called by muse, mutect2, varscan2
- ZNF577 | c.1093C>T p.H365Y | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100031043, COSV100031339; called by muse, mutect2, varscan2
- ZNF708 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100803106; called by muse, mutect2, varscan2
- ZNF99 | c.2300del p.G767Afs*15 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | catalogued as COSV68056222; called by mutect2, pindel, varscan2
- ZPLD1 | c.1205C>A p.T402K (on ENST00000466937 / NM_001329788.1; = p.T418K on NM_175056.2) | Missense Mutation (SNP) | VAF 62/368 reads (17%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.01); catalogued as COSV100083244; called by muse, mutect2, varscan2
- ZSCAN1 | c.778C>A p.R260S | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV56601700, COSV99991703; called by muse, mutect2, varscan2
- CCT3 | c.1153_1154del p.S385Gfs*91 | Frame Shift Del (DEL) | VAF 36/190 reads (19%) | called by pindel, varscan2
- IGLV1-50 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 93/336 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- IL1RAP | c.561del p.F187Lfs*4 | Frame Shift Del (DEL) | VAF 33/79 reads (42%) | called by mutect2, pindel, varscan2
- KMT2D | c.4200_4205delinsG p.C1400Wfs*30 | Frame Shift Del (DEL) | VAF 25/98 reads (26%) | called by pindel, varscan2*
- MAGEB6B | c.574G>C p.G192R | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MCOLN1 | c.838del p.H280Tfs*92 | Frame Shift Del (DEL) | VAF 15/87 reads (17%) | called by mutect2, pindel, varscan2
- MEX3C | c.1516G>C p.A506P | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- MRC1 | c.3940C>A p.P1314T | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- PRAMEF20 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRSS36 | c.73+1del p.X25_splice | Splice Site (DEL) | VAF 80/302 reads (26%) | called by mutect2, pindel, varscan2
- SLC35F6 | c.473T>G p.V158G | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TBX5 | c.288del p.T98Rfs*26 | Frame Shift Del (DEL) | VAF 59/238 reads (25%) | called by mutect2, pindel, varscan2
- WDPCP | c.1436G>A p.G479D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACSM2A | c.546G>T p.L182= (on ENST00000219054; = p.L103= on NM_001308169.2) | Silent (SNP) | VAF 108/460 reads (23%) | catalogued as COSV99525265; called by muse, mutect2, varscan2
- ADCY5 | c.3714G>T p.R1238= | Silent (SNP) | VAF 180/378 reads (48%) | catalogued as COSV100567694; called by muse, varscan2
- ALOX15B | c.900C>A p.T300= | Silent (SNP) | VAF 39/165 reads (24%) | catalogued as COSV101205620, COSV101205677; called by muse, mutect2, varscan2
- ATF2 | c.1368G>T p.S456= | Silent (SNP) | VAF 52/107 reads (49%) | catalogued as rs1354105737, COSV99908720; called by muse, mutect2, varscan2
- B4GALT7 | c.360C>T p.S120= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as rs758058316, COSV99218993; called by muse, mutect2, varscan2
- BMP15 | c.393T>A p.V131= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as COSV99399376; called by muse, mutect2, varscan2
- BPIFB6 | c.396C>T p.F132= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV100848517; called by muse, mutect2, varscan2
- CCDC173 | c.963T>C p.L321= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV101506329; called by muse, mutect2, varscan2
- CCL18 | c.183C>A p.L61= | Silent (SNP) | VAF 65/164 reads (40%) | called by muse, mutect2, varscan2
- CDH10 | c.807C>T p.F269= | Silent (SNP) | VAF 59/167 reads (35%) | catalogued as COSV100051552, COSV52568750; called by muse, mutect2, varscan2
- CDHR3 | c.1410G>A p.V470= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100488374; called by muse, mutect2, varscan2
- CDRT1 | c.1590G>T p.T530= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as rs1418220684, COSV100599778, COSV100599877; called by muse, mutect2, varscan2
- CDX2 | c.573G>T p.V191= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV101122683; called by muse, mutect2, varscan2
- CECR2 | c.1879C>A p.R627= (on ENST00000342247 / NM_001290047.2; = p.R444= on NM_001290046.1) | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as COSV99378009; called by muse, mutect2, varscan2
- CELF2 | c.1152C>G p.T384= (on ENST00000416382 / NM_001025077.3; = p.T397= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV100257600; called by muse, mutect2, varscan2
- CLCN2 | c.300C>A p.L100= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99658589; called by muse, mutect2, varscan2
- CSGALNACT1 | c.156G>A p.T52= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs371603397, COSV100175825; called by muse, mutect2, varscan2
- DDX60L | c.3630C>T p.H1210= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV99487639; called by muse, mutect2, varscan2
- DEFB134 | c.27C>A p.V9= | Silent (SNP) | VAF 26/219 reads (12%) | catalogued as COSV101198491; called by muse, mutect2, varscan2
- DSP | c.564C>T p.T188= | Silent (SNP) | VAF 51/159 reads (32%) | catalogued as COSV101131285; called by muse, mutect2, varscan2
- FAM47C | c.2361C>T p.H787= | Silent (SNP) | VAF 41/64 reads (64%) | catalogued as COSV100792576; called by muse, mutect2, varscan2
- FAM47C | c.2841G>A p.L947= | Silent (SNP) | VAF 54/110 reads (49%) | catalogued as COSV63725419; called by muse, mutect2, varscan2
- FAM71B | c.1764C>T p.G588= | Silent (SNP) | VAF 116/269 reads (43%) | catalogued as COSV100262119; called by muse, mutect2, varscan2
- FFAR3 | c.726C>T p.N242= | Silent (SNP) | VAF 29/272 reads (11%) | catalogued as rs147416906, COSV59909420; called by muse, mutect2, varscan2
- FH | c.963G>T p.L321= | Silent (SNP) | VAF 48/106 reads (45%) | catalogued as COSV100845024; called by muse, mutect2, varscan2
- GALNT13 | c.1338C>G p.G446= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as COSV101223035, COSV67237071; called by muse, mutect2, varscan2
- GATA4 | c.726C>A p.G242= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV100632876; called by muse, mutect2, varscan2
- GID4 | c.567C>T p.R189= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as COSV99254177; called by muse, varscan2
- GNB3 | c.291C>T p.S97= | Silent (SNP) | VAF 37/217 reads (17%) | catalogued as COSV51834202; called by muse, varscan2
- GRM3 | c.2286A>C p.P762= | Silent (SNP) | VAF 54/118 reads (46%) | catalogued as COSV100862558; called by muse, mutect2, varscan2
- HMGB4 | c.411G>T p.L137= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV99590186; called by muse, mutect2, varscan2
- HTR5A | c.183G>T p.V61= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99839719; called by muse, mutect2, varscan2
- IGDCC3 | c.219C>T p.I73= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100031148; called by muse, mutect2, varscan2
- IGF2 | c.198G>A p.L66= (on ENST00000434045 / NM_001127598.3; = p.L10= on NM_000612.6) | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs760509523, COSV100324060; called by muse, mutect2, varscan2
- IGHV2-26 | c.312C>A p.T104= | Silent (SNP) | VAF 43/243 reads (18%) | called by muse, mutect2, varscan2
- IGKV1-6 | c.213T>C p.Y71= | Silent (SNP) | VAF 92/419 reads (22%) | catalogued as rs1414225913; called by muse, mutect2, varscan2
- IL17A | c.423C>A p.S141= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs17878530, COSV100391537; called by muse, mutect2, varscan2
- INTS3 | c.1956G>A p.L652= | Silent (SNP) | VAF 91/194 reads (47%) | catalogued as rs749723501, COSV100016033; called by muse, mutect2, varscan2
- IQCE | c.1263C>T p.L421= | Silent (SNP) | VAF 47/178 reads (26%) | catalogued as COSV100383403; called by muse, mutect2, varscan2
- KANK2 | c.2367G>T p.G789= (on ENST00000586659 / NM_001379562.1; = p.G797= on NM_015493.7 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV100763217; called by muse, mutect2, varscan2
- KERA | c.507C>A p.T169= | Silent (SNP) | VAF 51/215 reads (24%) | catalogued as rs142473139, COSV57131999; called by muse, mutect2, varscan2
- KIAA1755 | c.2859G>C p.T953= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99642072, COSV99642631; called by muse, mutect2, varscan2
- MAGEC2 | c.504G>C p.L168= | Silent (SNP) | VAF 99/181 reads (55%) | catalogued as COSV99909609; called by muse, mutect2, varscan2
- MASP1 | c.1959G>C p.L653= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV100537277; called by muse, mutect2
- MRGPRX1 | c.123G>A p.G41= | Silent (SNP) | VAF 48/184 reads (26%) | catalogued as rs747012199, COSV100245995; called by muse, mutect2, varscan2
- MTTP | c.606G>T p.T202= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as COSV55503618, COSV99645192; called by muse, mutect2, varscan2
- MUC6 | c.6321C>T p.I2107= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV101424597; called by muse, mutect2, varscan2
- MYCBP2 | c.4218A>G p.L1406= (on ENST00000357337; = p.L1444= on NM_015057.5) | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as rs1481419357, COSV100630428; called by muse, mutect2, varscan2
- MYH6 | c.162G>T p.R54= | Silent (SNP) | VAF 102/632 reads (16%) | catalogued as COSV100676601, COSV62453921; called by muse, mutect2, varscan2
- MYO16 | c.4899C>A p.P1633= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV100696729; called by muse, mutect2, varscan2
- MYO5C | c.2010G>T p.L670= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV99954763; called by muse, mutect2
- MYO7A | c.2028C>T p.Y676= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as CM071033, COSV101289135; called by muse, mutect2, varscan2
- NGFR | c.633C>T p.S211= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs777853819, COSV99412891; called by muse, mutect2, varscan2
- NLRX1 | c.327C>T p.V109= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as COSV99424284; called by muse, mutect2, varscan2
- NTRK2 | c.351G>T p.L117= | Silent (SNP) | VAF 78/170 reads (46%) | catalogued as COSV52875940; called by muse, mutect2, varscan2
- NUTM1 | c.609C>T p.R203= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV100412326; called by muse, mutect2, varscan2
- OR14C36 | c.609G>A p.G203= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as COSV100507543; called by muse, mutect2, varscan2
- OR4A15 | c.606A>T p.G202= | Silent (SNP) | VAF 40/138 reads (29%) | catalogued as COSV100124098; called by muse, mutect2, varscan2
- OR51Q1 | c.567G>T p.L189= | Silent (SNP) | VAF 78/262 reads (30%) | catalogued as COSV100332941; called by muse, mutect2, varscan2
- OR5F1 | c.387G>T p.P129= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV99558653; called by muse, mutect2, varscan2
- OR6C75 | c.846C>A p.L282= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as rs1447703826, COSV100595340, COSV58553084; called by muse, mutect2, varscan2
- OR8B8 | c.348A>T p.S116= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as COSV100045043; called by muse, mutect2
- OR9I1 | c.741T>C p.A247= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV100109979; called by muse, mutect2, varscan2
- PCDH18 | c.3363G>T p.L1121= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as COSV100787321; called by muse, mutect2
- PCDHGA3 | c.585G>T p.V195= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as COSV99538658; called by muse, mutect2, varscan2
- PCDHGB2 | c.237A>T p.P79= | Silent (SNP) | VAF 81/201 reads (40%) | catalogued as COSV99538661; called by muse, mutect2, varscan2
- PLEKHG7 | c.33G>T p.V11= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV101188854; called by muse, mutect2, varscan2
- PMS1 | c.2073T>C p.S691= | Silent (SNP) | VAF 22/135 reads (16%) | catalogued as COSV100575654; called by muse, mutect2, varscan2
- RDH12 | c.771G>A p.T257= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as COSV99961854; called by muse, mutect2, varscan2
- RDX | c.870A>G p.L290= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as rs1321513562, COSV100562933; called by muse, mutect2, varscan2
- SART3 | c.2232C>T p.F744= (on ENST00000228284; = p.F726= on NM_014706.4) | Silent (SNP) | VAF 9/117 reads (8%) | catalogued as rs1362204105, COSV99934081; called by muse, mutect2
- SCN7A | c.63A>T p.I21= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV101313240; called by muse, mutect2, varscan2
- SEMA5A | c.1824C>T p.S608= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV101228303; called by muse, mutect2, varscan2
- SGCE | c.1122C>T p.I374= (on ENST00000647096; = p.I338= on NM_003919.3) | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV99722589; called by muse, mutect2, varscan2
- SLC12A3 | c.2715T>A p.A905= (on ENST00000563236 / NM_001126108.2; = p.A914= on NM_000339.3) | Silent (SNP) | VAF 51/147 reads (35%) | catalogued as COSV99344259, COSV99344328; called by muse, mutect2, varscan2
- SLC16A9 | c.786A>T p.T262= | Silent (SNP) | VAF 121/242 reads (50%) | catalogued as COSV101264392; called by muse, mutect2
- SLC17A6 | c.147C>A p.P49= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV99581500; called by muse, mutect2, varscan2
- SLC39A1 | c.738C>T p.F246= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV100135489; called by muse, mutect2
- SLC5A5 | c.1053C>A p.T351= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV99715068; called by muse, mutect2, varscan2
- SMARCA2 | c.1563G>A p.K521= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs148410896, COSV61810634; called by muse, mutect2, varscan2
- SPIDR | c.1029C>T p.L343= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as COSV99855135; called by muse, varscan2
- ST18 | c.1266T>C p.H422= | Silent (SNP) | VAF 119/395 reads (30%) | catalogued as rs1386182713, COSV99389703; called by muse, mutect2, varscan2
- STXBP5L | c.2415A>T p.T805= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV56520803, COSV99874215; called by muse, mutect2, varscan2
- TECTB | c.66A>G p.P22= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV101027703; called by muse, mutect2, varscan2
- TEX2 | c.1065G>C p.G355= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV99367131; called by muse, mutect2, varscan2
- THBS2 | c.729G>C p.T243= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV100827898; called by muse, mutect2, varscan2
- THSD7A | c.2523C>G p.R841= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV101448713; called by muse, mutect2, varscan2
- TOR1AIP1 | c.627A>G p.Q209= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV99621324; called by muse, mutect2, varscan2
- TPO | c.2664C>A p.G888= | Silent (SNP) | VAF 27/146 reads (18%) | catalogued as COSV100221098, COSV61105294; called by muse, mutect2, varscan2
- TRIM42 | c.1920C>A p.V640= | Silent (SNP) | VAF 79/255 reads (31%) | catalogued as COSV99648379; called by muse, mutect2, varscan2
- TRIML1 | c.825G>T p.T275= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100206012, COSV60193746; called by muse, mutect2, varscan2
- TTC16 | c.2058G>A p.E686= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV100262960; called by muse, mutect2, varscan2
- UTP15 | c.282G>A p.L94= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV99707028; called by muse, mutect2, varscan2
- VPS35L | c.2172C>G p.L724= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV99220795; called by muse, mutect2, varscan2
- ZBP1 | c.405G>A p.R135= | Silent (SNP) | VAF 94/331 reads (28%) | catalogued as COSV100473487, COSV100473593; called by muse, mutect2, varscan2
- ZBTB40 | c.2946G>T p.T982= | Silent (SNP) | VAF 65/163 reads (40%) | catalogued as COSV100988963; called by muse, mutect2, varscan2
- ZNF138 | c.285C>T p.S95= (on ENST00000307355 / NM_001367572.1; = p.S69= on NM_006524.4) | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as COSV100245761, COSV56467825; called by muse, mutect2, varscan2
- ZNF208 | c.3414G>A p.E1138= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV68101846, COSV68104706; called by muse, mutect2, varscan2
- ZNF524 | c.612G>T p.R204= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99684577; called by muse, mutect2, varscan2
- AGAP2 | chr12:57741925 C>A | 5'Flank (SNP) | VAF 59/223 reads (26%) | catalogued as COSV57731380, COSV99223229; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505640 C>T | 5'Flank (SNP) | VAF 58/177 reads (33%) | called by muse, mutect2, varscan2
- B4GALNT1 | chr12:57622856 A>T | 3'Flank (SNP) | VAF 28/109 reads (26%) | catalogued as COSV100247145; called by muse, mutect2, varscan2
- CD99 | c.475+962G>T | Intron (SNP) | VAF 19/69 reads (28%) | catalogued as COSV101152291; called by muse, mutect2
- GGTLC2 | c.360+39C>T | Intron (SNP) | VAF 32/208 reads (15%) | catalogued as rs764494098, COSV101312227; called by muse, mutect2, varscan2
- KCNU1 | c.2010-16883C>G | Intron (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2
- NAV3 | c.-2C>T | 5'UTR (SNP) | VAF 106/451 reads (24%) | catalogued as COSV99891201; called by muse, mutect2, varscan2
- PTBP1 | c.*1G>C | 3'UTR (SNP) | VAF 52/141 reads (37%) | catalogued as COSV100608699; called by muse, mutect2, varscan2
- RUBCNL | c.-122-5344C>A | Intron (SNP) | VAF 12/24 reads (50%) | catalogued as COSV100529088; called by muse, mutect2, varscan2
